Somatic mutation profile of tumor specimen TCGA-DF-A2KZ-01A (aliquot TCGA-DF-A2KZ-01A-11D-A20S-09) from TCGA case TCGA-DF-A2KZ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 87.5 years (31,973 days).
Specimen TCGA-DF-A2KZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 009e0ccf-9d22-4ce1-b1ab-afe17e2fb100.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DF-A2KZ-10A (Blood Derived Normal), aliquot TCGA-DF-A2KZ-10A-01D-A20S-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d17dceb-70dd-494f-9997-ece4ff96a073

The open-access MAF lists 745 somatic variants for this specimen: 572 protein-altering or splice-affecting, 157 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 375, Silent 157, Frame Shift Del 131, Nonsense Mutation 23, Frame Shift Ins 19, Splice Site 13, Intron 11, Splice Region 5, In Frame Del 5, 3'UTR 2, RNA 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.2870dup p.N957Kfs*10 | Frame Shift Ins (INS) | VAF 12/63 reads (19%) | catalogued as rs397517429; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AGXT | c.33del p.K12Rfs*34 | Frame Shift Del (DEL) | VAF 28/94 reads (30%) | catalogued as rs180177201, CM056286; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 5/23 reads (22%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- ATM | c.900del p.G301Vfs*19 | Frame Shift Del (DEL) | VAF 9/48 reads (19%) | catalogued as rs1555067335; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- BBS10 | c.1338del p.F446Lfs*42 | Frame Shift Del (DEL) | VAF 18/67 reads (27%) | catalogued as rs1389599028; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- KCNH2 | c.453del p.T152Pfs*14 | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | catalogued as rs761863251, CD001499; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 15/67 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- MAPK1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 20/44 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519911, COSV53184855, COSV99308005; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MYO7A | c.397del p.H133Tfs*13 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | catalogued as rs111033187; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 15/58 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 9/26 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.80-1_80del p.X27_splice | Splice Site (DEL) | VAF 23/47 reads (49%) | catalogued as rs1554893747; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AASDH | c.1319del p.L440Wfs*43 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | catalogued as rs770970036; called by mutect2, varscan2
- ABCA5 | c.742del p.I248* | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs751460805, COSV67017665; called by mutect2, varscan2
- ABLIM3 | c.509A>G p.Q170R | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100448250; called by muse, mutect2, varscan2
- ABR | c.814C>T p.R272C (on ENST00000302538 / NM_021962.5; = p.R235C on NM_001092.5) | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1296203288, COSV99347749; called by muse, mutect2, varscan2
- ACOT12 | c.1442del p.P481Rfs*63 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | catalogued as rs752709684; called by mutect2, pindel, varscan2
- ADAMTSL4 | c.1387G>T p.G463W | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99647025; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2041G>A p.G681R | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371872840; called by muse, mutect2, varscan2
- ADCY9 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99569755; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 6/13 reads (46%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRA1 | c.317C>T p.T106I | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.096); catalogued as COSV101658598; called by muse, mutect2, varscan2
- ADGRA3 | c.2843G>A p.R948H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs774357237, COSV51560877; called by muse, mutect2, varscan2
- ADGRB2 | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as rs747551189, COSV57073758; called by muse, mutect2
- ADRA2A | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99701592; called by muse, mutect2, varscan2
- AFAP1 | c.137T>C p.V46A | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.039); catalogued as COSV100631341; called by muse, mutect2
- AIF1L | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 25/78 reads (32%) | catalogued as rs779882634, COSV99908138, COSV99908295; called by muse, mutect2, varscan2
- AKAP9 | c.10257G>T p.Q3419H (on ENST00000359028; = p.Q3395H on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as COSV100662242; called by muse, mutect2, varscan2
- AKAP9 | c.11307dup p.Q3770Afs*52 (on ENST00000359028; = p.Q3746Afs*52 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 8/30 reads (27%) | catalogued as rs747796926; called by mutect2, varscan2
- ALDH1L1 | c.299A>G p.H100R | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.493); catalogued as rs1343932127, COSV99856701; called by muse, mutect2, varscan2
- ALDH7A1 | c.139C>G p.L47V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.634); catalogued as COSV101297449; called by muse, mutect2, varscan2
- ALK | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV66559039; called by muse, mutect2, varscan2
- AMBRA1 | c.2803C>T p.L935F (on ENST00000458649 / NM_001367468.1; = p.L845F on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100093419; called by muse, mutect2, varscan2
- AMIGO3 | c.637G>A p.G213S | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV100246526; called by muse, mutect2, varscan2
- AMN1 | c.349C>A p.L117I | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99861475; called by muse, mutect2, varscan2
- AMPD2 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.868); catalogued as rs1333072178, COSV56651107; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6440T>C p.V2147A | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV99782842; called by muse, mutect2, varscan2
- ANKRD13C | c.1417G>T p.V473L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV99256627; called by muse, mutect2, varscan2
- APOB | c.4516C>T p.Q1506* | Nonsense Mutation (SNP) | VAF 7/53 reads (13%) | catalogued as COSV99264957; called by mutect2, varscan2
- ARHGAP39 | c.715G>A p.G239R | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.133); catalogued as COSV99430828; called by muse, mutect2, varscan2
- ARHGEF19 | c.1513C>T p.R505C | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs368323780; called by muse, mutect2, varscan2
- ARID2 | c.1447C>T p.P483S | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.197); catalogued as rs374540100; called by muse, mutect2, varscan2
- ARVCF | c.2179C>T p.R727C | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.978); catalogued as rs556096878, COSV52889556; called by muse, mutect2, varscan2
- ASTN2 | c.3943A>G p.K1315E (on ENST00000313400 / NM_001365069.1; = p.K1264E on NM_014010.5) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as COSV99940615; called by muse, mutect2, varscan2
- ATP13A3 | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs1255670474, COSV99756811; called by muse, mutect2, varscan2
- ATP2A3 | c.2171C>T p.T724M | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770517233, COSV99989038; called by muse, mutect2, varscan2
- AURKA | c.122G>A p.S41N | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV100452920; called by muse, mutect2
- B4GALNT1 | c.556A>G p.T186A | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV100247044; called by muse, mutect2, varscan2
- BCLAF3 | c.1736C>T p.A579V | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.67); catalogued as COSV100503263; called by muse, mutect2, varscan2
- BCORL1 | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 20/64 reads (31%) | catalogued as COSV99499121, COSV99500505; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BCR | c.1038_1040del p.S347del | In Frame Del (DEL) | VAF 16/60 reads (27%) | catalogued as rs772823202; called by pindel, varscan2
- BCS1L | c.979G>A p.V327M | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.703); catalogued as rs774076186, COSV99828917; called by muse, mutect2, varscan2
- BMP7 | c.1142C>T p.T381M | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1275787189, COSV67781628; called by muse, mutect2, varscan2
- BMX | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100564409; called by muse, mutect2, varscan2
- BOK | c.356C>T p.T119M | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs759186943, COSV100572214; called by muse, mutect2, varscan2
- BRMS1 | c.457T>C p.Y153H | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as COSV100240210; called by muse, mutect2, varscan2
- BROX | c.413A>G p.D138G | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV100572156; called by muse, mutect2, varscan2
- BSN | c.6340C>T p.R2114W | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1180601293, COSV56523374; called by muse, mutect2, varscan2
- BTBD11 | c.1357del p.L453Cfs*53 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | catalogued as rs777776928; called by mutect2, pindel, varscan2
- BTNL3 | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.346); catalogued as COSV100732198; called by muse, mutect2, varscan2
- C12orf40 | c.818del p.N273Mfs*12 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | catalogued as COSV104410248; called by mutect2, pindel, varscan2
- C12orf50 | c.419T>C p.M140T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99037465; called by muse, mutect2, varscan2
- C12orf65 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV99473915; called by muse, mutect2, varscan2
- C1QC | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.09); catalogued as rs769724909, COSV65889552; called by muse, mutect2, varscan2
- C2CD6 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as rs1388418113, COSV99632524; called by muse, mutect2, varscan2
- C6orf62 | c.123G>T p.K41N | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.978); catalogued as COSV100965862; called by muse, mutect2
- C7orf57 | c.506del p.K169Sfs*2 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs747591930; called by mutect2, varscan2
- CACNB3 | c.989C>A p.P330Q | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs754339233, COSV99974813; called by muse, mutect2, varscan2
- CARD14 | c.356T>C p.M119T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV100712538; called by muse, mutect2, varscan2
- CAV2 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | catalogued as rs547905225, COSV56064400; called by muse, mutect2, varscan2
- CBFA2T3 | c.212C>T p.T71M | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.902); catalogued as rs779187993, COSV51930016, COSV99241443; called by muse, mutect2, varscan2
- CCDC191 | c.164A>G p.N55S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV99878115; called by muse, mutect2, varscan2
- CCDC22 | c.1840C>T p.R614C | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs904046877, COSV100873126; called by muse, mutect2, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs756347761; called by mutect2, varscan2
- CCDC39 | c.2188_2189insT p.E730Vfs*8 | Frame Shift Ins (INS) | VAF 17/66 reads (26%) | catalogued as COSV99868286; called by mutect2, pindel, varscan2
- CCDC57 | c.1909G>A p.G637R | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs201954226; called by muse, mutect2, varscan2
- CCDC69 | c.125-2A>G p.X42_splice | Splice Site (SNP) | VAF 11/43 reads (26%) | catalogued as rs927894983, COSV100815146; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | catalogued as rs762194001; called by mutect2, varscan2
- CDH18 | c.2162C>T p.A721V | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV99933724; called by mutect2, varscan2
- CDHR3 | c.578C>A p.T193K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100488195, COSV58419147; called by muse, mutect2, varscan2
- CDK11B | c.1744G>A p.G582R | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100477587; called by muse, mutect2, varscan2
- CDKL5 | c.2369C>T p.S790F | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.48); catalogued as COSV66114309; called by muse, mutect2, varscan2
- CENPH | c.239+1G>A p.X80_splice | Splice Site (SNP) | VAF 12/43 reads (28%) | catalogued as rs369923920; called by muse, mutect2, varscan2
- CFAP45 | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1026999934, COSV63648748; called by muse, mutect2, varscan2
- CFH | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as rs773509771, COSV62776437; called by muse, mutect2, varscan2
- CHD3 | c.4542G>A p.M1514I | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.061); catalogued as COSV100391040; called by muse, mutect2, varscan2
- CHD5 | c.3338A>G p.D1113G | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99313259; called by muse, mutect2, varscan2
- CHDH | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.02); catalogued as COSV100179646; called by muse, mutect2, varscan2
- CHMP2A | c.349C>T p.L117= | Splice Region (SNP) | VAF 18/60 reads (30%) | catalogued as COSV99448064; called by muse, mutect2, varscan2
- CHRNB1 | c.612G>A p.E204= | Splice Region (SNP) | VAF 22/59 reads (37%) | catalogued as rs754405279, COSV99548221, COSV99548361; ClinVar: likely benign; called by muse, mutect2, varscan2
- CLEC16A | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs202157918, COSV68498108; called by muse, mutect2, varscan2
- CLTCL1 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as rs376664009; called by muse, mutect2, varscan2
- CNGA3 | c.1792C>A p.L598M | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as COSV99736521; called by muse, mutect2, varscan2
- CNKSR1 | c.304G>T p.G102W | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100836725, COSV100836795; called by muse, mutect2, varscan2
- CNN2 | c.793G>T p.G265C | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99565566; called by muse, mutect2, varscan2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 20/44 reads (45%) | catalogued as rs758676375; called by mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 5/13 reads (38%) | catalogued as rs374805044; called by mutect2, varscan2
- COBLL1 | c.1946C>T p.A649V (on ENST00000392717; = p.A611V on NM_014900.5) | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV99527711; called by muse, mutect2, varscan2
- COIL | c.587del p.K196Rfs*13 | Frame Shift Del (DEL) | VAF 20/74 reads (27%) | catalogued as rs748995811; called by mutect2, varscan2
- COL11A1 | c.1635del p.P546Lfs*87 | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | catalogued as COSV100615079, COSV62186140; called by mutect2, pindel, varscan2
- COL3A1 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as COSV58596953; called by muse, mutect2, varscan2
- COL4A6 | c.4061C>T p.A1354V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.744); catalogued as COSV100563880; called by muse, mutect2, varscan2
- COL5A1 | c.769C>A p.P257T | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100879761; called by muse, mutect2, varscan2
- COL6A3 | c.3046G>A p.V1016M | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV55103287, COSV99797452; called by muse, mutect2, varscan2
- COL9A1 | c.848del p.P283Lfs*45 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | catalogued as rs941174282; called by mutect2, pindel, varscan2
- CR2 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs201201097, COSV100889596; called by muse, mutect2, varscan2
- CRACD | c.501del p.K167Nfs*82 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | catalogued as rs1180697484, COSV99950174; called by mutect2, pindel, varscan2
- CRB2 | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs756607676, COSV63503090; called by muse, mutect2, varscan2
- CREB5 | c.767G>T p.G256V (on ENST00000357727 / NM_182898.4; = p.G249V on NM_004904.3) | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757678260, COSV100744453; called by muse, mutect2, varscan2
- CRHR2 | c.647C>T p.T216I | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs140917893, COSV100529896; called by muse, mutect2, varscan2
- CRMP1 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.088); catalogued as rs548835481, COSV100271702; called by muse, mutect2, varscan2
- CRYBB2 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772533013, COSV101236726; called by muse, mutect2, varscan2
- CRYM | c.563G>A p.C188Y | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.66); catalogued as COSV99561701; called by muse, mutect2
- CSF2RA | c.527T>C p.V176A | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100817640; called by muse, mutect2
- CSF2RB | c.1600G>A p.V534M | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.843); catalogued as COSV99453652; called by muse, mutect2, varscan2
- CSGALNACT2 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs368373201; called by muse, mutect2, varscan2
- CSN1S1 | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs375053260; called by muse, mutect2, varscan2
- CTSB | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); catalogued as rs147640153; called by muse, mutect2, varscan2
- CUL1 | c.1739C>T p.T580M | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as rs758702023, COSV57392126; called by muse, mutect2, varscan2
- CYP4F11 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as rs770289390, COSV99930789; called by muse, mutect2
- DACH2 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748018424, COSV100912997, COSV99058303; called by muse, mutect2, varscan2
- DACT1 | c.2120C>T p.A707V | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV60019815; called by muse, mutect2, varscan2
- DAGLB | c.64G>T p.G22W | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51702119, COSV99765777; called by muse, mutect2, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 17/35 reads (49%) | catalogued as COSV99245498; called by mutect2, varscan2
- DCAF12L1 | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.057); catalogued as COSV100948217, COSV64421542; called by muse, mutect2, varscan2
- DEFA5 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs370324425; called by muse, varscan2
- DELE1 | c.1015G>T p.V339L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV99519754; called by muse, mutect2, varscan2
- DENND5A | c.2282A>C p.K761T | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60236994; called by muse, mutect2, varscan2
- DERA | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs779490135, COSV70775273; called by muse, mutect2, varscan2
- DGKA | c.2176del p.R726Afs*9 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as COSV59384233; called by mutect2, pindel, varscan2
- DHPS | c.137T>C p.L46P | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV99269573; called by muse, mutect2, varscan2
- DHX34 | c.2767G>A p.D923N | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs762160827, COSV100169450, COSV60895174; called by muse, mutect2, varscan2
- DHX38 | c.3477+2T>C p.X1159_splice | Splice Site (SNP) | VAF 19/63 reads (30%) | catalogued as COSV99194262; called by muse, mutect2, varscan2
- DMRT1 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs902482318, CM990487, COSV66522563; called by muse, mutect2, varscan2
- DMXL1 | c.2467-1G>A p.X823_splice | Splice Site (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100223737; called by muse, mutect2, varscan2
- DNAH2 | c.6319G>A p.A2107T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.041); catalogued as rs139080127; called by muse, mutect2, varscan2
- DNAH5 | c.13276G>A p.E4426K | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as rs777295839, COSV54202122; ClinVar: uncertain significance; called by muse, varscan2
- DNAH7 | c.1037del p.K346Sfs*23 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs761292636; called by mutect2, varscan2
- DNAJA3 | c.973A>G p.R325G | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as COSV99276615; called by muse, mutect2, varscan2
- DNHD1 | c.12781G>A p.A4261T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.79); PolyPhen benign (0.012); catalogued as COSV99599850; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 23/56 reads (41%) | catalogued as rs782552436; called by mutect2, varscan2
- DOCK8 | c.3339del p.F1113Lfs*2 | Frame Shift Del (DEL) | VAF 22/60 reads (37%) | catalogued as rs748134881; called by mutect2, varscan2
- DPP3 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as COSV100855545; called by muse, mutect2, varscan2
- DRD4 | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as COSV99448603; called by muse, mutect2, varscan2
- DTX3 | c.206del p.P69Rfs*9 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | catalogued as COSV54088851; called by mutect2, pindel, varscan2
- DUSP21 | c.43C>T p.Q15* | Nonsense Mutation (SNP) | VAF 17/49 reads (35%) | catalogued as COSV100173549; called by muse, mutect2, varscan2
- E2F1 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58535777; called by muse, mutect2, varscan2
- EBAG9 | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | catalogued as COSV100520790; called by muse, mutect2
- EHD3 | c.1346A>C p.D449A | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.948); catalogued as COSV100434671; called by muse, mutect2, varscan2
- ELAC2 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.421); catalogued as COSV100568440; called by muse, mutect2, varscan2
- ELOVL1 | c.155A>C p.N52T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100196409; called by muse, mutect2, varscan2
- ELP1 | c.3194C>T p.A1065V | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs972475636, COSV65897024; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPHB6 | c.165+1dup | Frame Shift Ins (INS) | VAF 16/59 reads (27%) | catalogued as rs771807343; called by mutect2, varscan2
- EPS8L2 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); catalogued as COSV100585472; called by muse, mutect2
- ERICH1 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs369345572, COSV100032339; called by muse, mutect2, varscan2
- ERN2 | c.1744C>T p.R582W | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1365755215, COSV99891207; called by muse, mutect2, varscan2
- ESYT2 | c.1136G>A p.R379Q (on ENST00000613624; = p.R303Q on NM_020728.3) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs767514684, COSV51749013, COSV51756836; called by muse, mutect2, varscan2
- ETV6 | c.115C>T p.R39* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as rs1036410712, COSV67151820; called by muse, mutect2, varscan2
- FAM71F2 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.086); catalogued as rs367837931, COSV66352105; called by muse, mutect2, varscan2
- FARP2 | c.1214C>A p.A405D | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.299); catalogued as COSV99884383; called by muse, mutect2
- FAXDC2 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as rs748240055, COSV58171469; called by muse, mutect2, varscan2
- FBH1 | c.314A>G p.Q105R (on ENST00000362091 / NM_178150.3; = p.Q156R on NM_032807.4) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV100758694; called by muse, mutect2, varscan2
- FBN2 | c.7659del p.F2554Lfs*57 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | catalogued as rs748600284, COSV99331968; called by mutect2, pindel, varscan2
- FGR | c.961C>A p.L321M | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100925801; called by muse, mutect2, varscan2
- FLNB | c.283G>C p.V95L | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99912624; called by muse, mutect2, varscan2
- FLNB | c.7003G>A p.V2335M | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs147537617; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLRT3 | c.438A>C p.E146D | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99429941; called by mutect2, varscan2
- FLYWCH1 | c.1283del p.G428Afs*44 (on ENST00000253928 / NM_001308068.2; = p.G427Afs*44 on NM_020912.1 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 34/99 reads (34%) | catalogued as rs1378433610; called by mutect2, pindel, varscan2
- FMNL3 | c.2657G>A p.R886Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs759869506, COSV53309535; called by muse, mutect2, varscan2
- FN1 | c.685+1G>T p.X229_splice | Splice Site (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100116832; called by muse, mutect2, varscan2
- FNIP1 | c.1478T>C p.L493S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV100330373; called by muse, mutect2, varscan2
- FRMPD1 | c.4079C>T p.A1360V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as rs773617590, COSV100899534; called by muse, mutect2, varscan2
- FRYL | c.989del p.L330* | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as rs1348158626; called by mutect2, varscan2
- GABRB2 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99195877; called by muse, mutect2, varscan2
- GANAB | c.266T>C p.L89P | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100647962; called by muse, mutect2
- GCC2 | c.4931C>T p.T1644M | Missense Mutation (SNP) | VAF 44/387 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs746575083, COSV59180015; called by muse, mutect2, varscan2
- GLIPR1L1 | c.124A>G p.N42D | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs905843198, COSV56883036; called by muse, mutect2, varscan2
- GLS2 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.086); catalogued as rs1298789195, COSV57665888; called by muse, mutect2, varscan2
- GMEB2 | c.1400C>A p.T467K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.831); catalogued as COSV99823569; called by muse, mutect2, varscan2
- GNL2 | c.1414del p.Q472Sfs*140 | Frame Shift Del (DEL) | VAF 4/19 reads (21%) | catalogued as rs758338395, COSV66081403; called by mutect2, pindel, varscan2
- GOLGB1 | c.8679+2T>C p.X2893_splice | Splice Site (SNP) | VAF 9/44 reads (20%) | catalogued as COSV100510654; called by muse, mutect2, varscan2
- GPAT3 | c.452T>C p.V151A | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV100022937; called by muse, mutect2, varscan2
- GPR108 | c.1556A>G p.Q519R (on ENST00000264080 / NM_001080452.1; = p.Q277R on NM_020171.2) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV99901274; called by muse, mutect2, varscan2
- GPR149 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.092); catalogued as rs749611848, COSV101078301; called by muse, mutect2, varscan2
- GPR152 | c.1379C>T p.P460L | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); catalogued as rs546905508, COSV100351486; called by muse, mutect2, varscan2
- GPRC6A | c.1355del p.N452Mfs*2 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | catalogued as rs1362947110; called by mutect2, pindel, varscan2
- GREB1 | c.2151A>G p.S717= | Splice Region (SNP) | VAF 11/48 reads (23%) | catalogued as COSV99302721; called by muse, mutect2, varscan2
- GRIP2 | c.3388C>T p.R1130* (on ENST00000619221; = p.R1033* on NM_001080423.4) | Nonsense Mutation (SNP) | VAF 13/55 reads (24%) | catalogued as rs753190956, COSV99817170, COSV99817519; called by muse, mutect2, varscan2
- GRM4 | c.2476G>A p.V826M | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.815); catalogued as rs889185388, COSV100946051; called by muse, mutect2
- GRM8 | c.2681C>A p.S894Y | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV58829885, COSV58875055; called by muse, mutect2, varscan2
- GTF3A | c.905A>G p.D302G | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100820190; called by muse, mutect2, varscan2
- GTF3C2 | c.2111G>A p.R704Q | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV53126663; called by muse, mutect2, varscan2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | catalogued as COSV54945907; called by mutect2, varscan2
- H2BC18 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.069); catalogued as COSV100516073; called by muse, mutect2, varscan2
- H6PD | c.986G>T p.S329I | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV101072447; called by muse, mutect2
- HADHA | c.1990A>G p.K664E | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as rs755891307, COSV101023853; called by muse, mutect2, varscan2
- HCRTR2 | c.928C>A p.L310I | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); catalogued as COSV100904285; called by muse, mutect2, varscan2
- HDAC10 | c.1474G>T p.D492Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.153); catalogued as COSV99352262; called by muse, mutect2, varscan2
- HIVEP3 | c.2899C>T p.R967C | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs141506685; called by muse, mutect2, varscan2
- HK1 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.208); catalogued as rs1177686967, COSV53860840; called by muse, mutect2, varscan2
- HNRNPDL | c.1229del p.G410Vfs*25 | Frame Shift Del (DEL) | VAF 28/88 reads (32%) | catalogued as COSV99040410; called by mutect2, pindel, varscan2
- HSPG2 | c.2918C>A p.P973H | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.417); catalogued as COSV101020601; called by muse, mutect2, varscan2
- HYKK | c.533T>C p.L178P | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV101195032; called by muse, mutect2, varscan2
- ICE1 | c.5809G>A p.V1937M | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs747811719, COSV99664385; called by mutect2, varscan2
- IFT140 | c.3787C>T p.P1263S | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as COSV100794255; called by muse, mutect2, varscan2
- IKBKE | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as COSV100898188; called by muse, mutect2, varscan2
- IKZF3 | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as COSV99499500; called by muse, mutect2, varscan2
- IL1F10 | c.52A>G p.K18E | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as COSV100520156; called by muse, mutect2, varscan2
- IL22RA1 | c.362T>C p.L121P | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99582898; called by muse, mutect2, varscan2
- ILDR1 | c.544C>A p.L182M | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV99878188; called by muse, mutect2, varscan2
- IMMT | c.970A>G p.I324V | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.401); catalogued as COSV99607167; called by muse, mutect2, varscan2
- INTS1 | c.5380G>A p.V1794M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.148); catalogued as rs773961874, COSV101247800; called by muse, varscan2
- ITGA10 | c.1265del p.P422Lfs*50 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | catalogued as rs782013321; called by mutect2, pindel
- ITGA4 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as rs901057020, COSV51998204; called by muse, mutect2, varscan2
- ITGA4 | c.2816G>A p.R939K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100183505; called by muse, mutect2, varscan2
- ITM2A | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV64811624; called by muse, mutect2, varscan2
- ITPRID2 | c.3319del p.S1107Pfs*36 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | catalogued as rs1318064731; called by mutect2, pindel, varscan2
- ITSN1 | c.1082G>A p.G361D | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101180472; called by muse, mutect2, varscan2
- IVNS1ABP | c.1431del p.G478Dfs*2 | Frame Shift Del (DEL) | VAF 14/45 reads (31%) | catalogued as COSV62252045; called by mutect2, pindel, varscan2
- JAG2 | c.3166C>T p.R1056W | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs371312658; called by muse, mutect2, varscan2
- JAK1 | c.1758C>T p.G586= | Splice Region (SNP) | VAF 22/56 reads (39%) | catalogued as rs199920803, COSV61096113; called by muse, varscan2
- KANK1 | c.3392C>T p.A1131V | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as COSV100619652; called by muse, mutect2, varscan2
- KANSL1 | c.611del p.G204Vfs*2 | Frame Shift Del (DEL) | VAF 12/61 reads (20%) | catalogued as rs1304078301; called by mutect2, varscan2
- KAT14 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as rs760685954, COSV100890062; called by muse, mutect2, varscan2
- KCNQ2 | c.2299C>T p.R767W (on ENST00000359125 / NM_172107.4; = p.R739W on NM_004518.6) | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); catalogued as rs755823361, COSV60552460; ClinVar: uncertain significance; called by muse, mutect2
- KIAA1217 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1329375308, COSV100907944; called by muse, mutect2, varscan2
- KIF17 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs199932440; called by muse, mutect2, varscan2
- KIF1B | c.4586C>T p.S1529L (on ENST00000377086 / NM_001365952.1; = p.S1483L on NM_015074.3) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs781051649, COSV55803817; called by muse, mutect2, varscan2
- KIF3B | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100996357; called by muse, mutect2, varscan2
- KMT2D | c.10763A>G p.H3588R | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99979983; called by muse, mutect2, varscan2
- KMT2D | c.6121C>A p.R2041S | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56442695, COSV56466619, COSV99979985; called by muse, mutect2, varscan2
- KNDC1 | c.2888C>T p.A963V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs776648690, COSV58842260; called by muse, varscan2
- KRBA2 | c.1165C>T p.R389* | Nonsense Mutation (SNP) | VAF 3/16 reads (19%) | catalogued as rs368681596; called by muse, mutect2
- KRT72 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as rs151190349; called by muse, mutect2, varscan2
- KRT76 | c.1621A>G p.S541G | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs372674456; called by muse, mutect2, varscan2
- KRTAP24-1 | c.270C>G p.N90K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.502); catalogued as COSV100447400; called by muse, mutect2, varscan2
- KRTAP27-1 | c.89T>C p.F30S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV101239702; called by muse, mutect2, varscan2
- LACTB2 | c.58G>T p.G20C | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99399382; called by muse, mutect2, varscan2
- LAMA4 | c.889G>A p.G297R (on ENST00000230538 / NM_001105206.3; = p.G290R on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.337); catalogued as rs375305822; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAP3 | c.1343C>T p.A448V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.942); catalogued as COSV99884222; called by muse, mutect2, varscan2
- LARGE1 | c.1549G>A p.A517T | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.313); catalogued as rs148771159; called by muse, mutect2, varscan2
- LCE1C | c.9C>A p.C3* | Nonsense Mutation (SNP) | VAF 39/68 reads (57%) | catalogued as COSV100908432; called by muse, mutect2, varscan2
- LIPC | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as rs545537175, COSV100134429; called by muse, mutect2, varscan2
- LMLN | c.1760G>A p.W587* | Nonsense Mutation (SNP) | VAF 22/53 reads (42%) | catalogued as COSV57605254; called by muse, mutect2, varscan2
- LMO7 | c.1744G>A p.E582K (on ENST00000357063; = p.E312K on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.844); catalogued as rs747689599, COSV100412908; called by muse, varscan2
- LNX1 | c.1813G>A p.A605T (on ENST00000263925 / NM_001126328.3; = p.A509T on NM_032622.2) | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.08); catalogued as rs1480818801; called by muse, mutect2
- LRP6 | c.2828C>T p.A943V | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.198); catalogued as COSV99742980; called by muse, mutect2, varscan2
- LRRC58 | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.656); catalogued as COSV99820140; called by muse, mutect2, varscan2
- LRRC66 | c.1255G>A p.A419T | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs1440586203, COSV58634124; called by muse, mutect2, varscan2
- LRRC8C | c.1524del p.W509Gfs*13 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | catalogued as rs762972819; called by mutect2, pindel, varscan2
- LYZL4 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV99821196; called by muse, mutect2, varscan2
- MAOB | c.868C>G p.P290A | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1308300908, COSV100955994; called by muse, mutect2, varscan2
- MAP1A | c.5461C>A p.P1821T | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.177); catalogued as COSV100288437; called by muse, mutect2, varscan2
- MAPK7 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759623746, COSV100218821, COSV100218879; called by muse, mutect2, varscan2
- MAPT | c.1733-1G>T p.X578_splice (on ENST00000262410 / NM_001377265.1; = p.X186_splice on NM_005910.5) | Splice Site (SNP) | VAF 20/45 reads (44%) | catalogued as COSV99290246; called by muse, mutect2, varscan2
- MCHR2 | c.309del p.P104Lfs*21 | Frame Shift Del (DEL) | VAF 15/42 reads (36%) | catalogued as rs902197100; called by mutect2, pindel, varscan2
- MED12L | c.1741G>C p.A581P | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56370089, COSV56380524; called by muse, mutect2, varscan2
- MEGF8 | c.3583C>T p.R1195W (on ENST00000251268 / NM_001271938.2; = p.R1128W on NM_001410.3) | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1568567218, COSV99235539; called by muse, mutect2, varscan2
- MFSD6L | c.648del p.N221Ifs*39 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | catalogued as rs1567554310, COSV100266770; called by mutect2, pindel
- MGAT3 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.244); catalogued as rs747893252, COSV100361829; called by muse, mutect2, varscan2
- MIA2 | c.176del p.L59Cfs*22 | Frame Shift Del (DEL) | VAF 32/109 reads (29%) | catalogued as rs769553721, COSV54495286; called by mutect2, varscan2
- MIDEAS | c.2724+2T>C p.X908_splice | Splice Site (SNP) | VAF 6/51 reads (12%) | catalogued as COSV99678783; called by muse, mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MINK1 | c.3488G>A p.R1163H | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1370638630, COSV53417384; called by muse, mutect2, varscan2
- MLH1 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs63750760, CM022425, COSV51614892; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MMP24 | c.1517C>T p.T506M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.019); catalogued as rs765652129, COSV55769918; called by mutect2, varscan2
- MOB3C | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV99596278; called by muse, mutect2, varscan2
- MON1B | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.349); catalogued as rs781298641, COSV99941649; called by muse, mutect2, varscan2
- MRGPRX3 | c.560del p.L187Yfs*25 | Frame Shift Del (DEL) | VAF 43/157 reads (27%) | catalogued as rs1178892676; called by mutect2, pindel, varscan2
- MRPL2 | c.544C>G p.H182D | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV99431706; called by muse, mutect2, varscan2
- MS4A1 | c.708del p.E237Nfs*6 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | catalogued as rs779922206; called by mutect2, varscan2
- MSI1 | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs149956156; called by muse, mutect2, varscan2
- MUC2 | c.1808C>T p.S603L | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs575230381; called by muse, mutect2
- MUC4 | c.1372G>T p.G458C | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV100640255; called by muse, mutect2, varscan2
- MUL1 | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV99939359; called by muse, mutect2, varscan2
- MYH3 | c.271A>G p.M91V | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.132); catalogued as rs79952473; called by muse, mutect2, varscan2
- MYNN | c.1333T>C p.C445R | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100581934; called by muse, mutect2, varscan2
- MYO1A | c.1682del p.P561Rfs*15 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | catalogued as rs746990682; called by mutect2, pindel, varscan2
- MYO1B | c.3160-1G>T p.X1054_splice (on ENST00000304164; = p.X996_splice on NM_012223.5) | Splice Site (SNP) | VAF 21/48 reads (44%) | catalogued as COSV100268960; called by muse, mutect2, varscan2
- MYT1 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV100114426; called by mutect2, varscan2
- N4BP2 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.207); catalogued as rs773346400, COSV99788510; called by muse, mutect2, varscan2
- NAT16 | c.365A>C p.E122A | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV100296242, COSV100296246; called by muse, mutect2
- NAV2 | c.2087C>T p.A696V (on ENST00000396087 / NM_001244963.2; = p.A673V on NM_145117.5) | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100585558; called by muse, mutect2, varscan2
- NBR1 | c.480G>A p.T160= | Splice Region (SNP) | VAF 10/55 reads (18%) | catalogued as rs760293145, COSV100357771; called by muse, mutect2, varscan2
- NCKAP5 | c.3343G>A p.V1115I | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.913); catalogued as COSV100491275; called by muse, mutect2, varscan2
- NCR2 | c.790A>G p.R264G | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); catalogued as COSV100897208; called by muse, mutect2, varscan2
- NDUFB6 | c.258G>A p.M86I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100598285; called by muse, mutect2, varscan2
- NIPBL | c.8326del p.I2776Lfs*3 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | catalogued as rs1157335847; called by mutect2, pindel, varscan2
- NKPD1 | c.2366C>T p.A789V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.015); catalogued as COSV99674818; called by muse, mutect2, varscan2
- NLRP2 | c.1838A>G p.Q613R | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99672154; called by muse, mutect2, varscan2
- NLRP9 | c.1115T>A p.L372* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as rs1345256027, COSV100242902; called by muse, mutect2, varscan2
- NOC3L | c.2225C>T p.A742V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as COSV100993296; called by mutect2, varscan2
- NPHP1 | c.2132A>G p.H711R (on ENST00000393272 / NM_207181.4; = p.H712R on NM_000272.5) | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1243062227, COSV100337966; called by muse, mutect2, varscan2
- NPIPB7 | c.25A>G p.I9V | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); catalogued as COSV101510521; called by muse, mutect2, varscan2
- NPTN | c.892A>G p.T298A | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99766399; called by muse, mutect2
- NT5M | c.622del p.R208Afs*34 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as rs754390000; called by mutect2, pindel, varscan2
- NUP205 | c.4097A>G p.H1366R | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.87); PolyPhen benign (0.01); catalogued as rs750201882, COSV99606797; called by muse, mutect2, varscan2
- NUP42 | c.212dup p.S72Qfs*13 | Frame Shift Ins (INS) | VAF 10/37 reads (27%) | catalogued as rs758695627; called by mutect2, varscan2
- NXF1 | c.1472T>C p.L491P | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99585946; called by muse, mutect2, varscan2
- NXF1 | c.260A>G p.H87R | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV99585947; called by muse, mutect2, varscan2
- OBSCN | c.18295C>A p.L6099M | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99476206; called by muse, mutect2
- OPN1LW | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.616); catalogued as COSV64063716; called by muse, mutect2, varscan2
- OR11H6 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.681); catalogued as COSV100209771, COSV59643996; called by muse, mutect2, varscan2
- OR2AG2 | c.772A>G p.M258V | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.192); catalogued as rs771431828, COSV58455329; called by muse, mutect2, varscan2
- OR4C13 | c.293A>G p.Q98R | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1214926001, COSV101634161; called by muse, mutect2, varscan2
- OR6K6 | c.623A>T p.D208V (on ENST00000368144; = p.D184V on NM_001005184.1) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1275893807, COSV63744301; called by muse, mutect2, varscan2
- OR6K6 | c.935del p.F312Sfs*8 (on ENST00000368144; = p.F288Sfs*8 on NM_001005184.1) | Frame Shift Del (DEL) | VAF 7/70 reads (10%) | catalogued as COSV63743557; called by mutect2, pindel, varscan2
- ORC4 | c.1030T>A p.F344I | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV99932094; called by muse, mutect2, varscan2
- OS9 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (1); PolyPhen probably damaging (0.995); catalogued as rs991502413, COSV99232703; called by muse, mutect2, varscan2
- OTOA | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142693996; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OXNAD1 | c.676-1G>T p.X226_splice | Splice Site (SNP) | VAF 5/21 reads (24%) | catalogued as COSV99551143; called by muse, mutect2, varscan2
- PACSIN1 | c.1171C>T p.R391W | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99763002; called by muse, mutect2, varscan2
- PADI1 | c.1268C>T p.T423M | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs376765489; called by muse, mutect2, varscan2
- PAMR1 | c.1991A>G p.E664G (on ENST00000619888 / NM_001001991.3; = p.E681G on NM_015430.4) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.538); catalogued as COSV99552438; called by muse, mutect2, varscan2
- PARD3 | c.1487G>A p.R496Q | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as rs12570964, COSV100400753, COSV60745413, COSV60751463; called by muse, mutect2, varscan2
- PARD3 | c.1366del p.I456* | Frame Shift Del (DEL) | VAF 16/51 reads (31%) | catalogued as rs1484598500; called by mutect2, pindel, varscan2
- PBRM1 | c.2570C>T p.T857I | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99968245; called by muse, mutect2, varscan2
- PCDH17 | c.1277C>T p.T426I | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV100931560, COSV64978242; called by muse, mutect2, varscan2
- PCDH17 | c.2056G>A p.G686R | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.552); catalogued as COSV64972702; called by muse, mutect2, varscan2
- PCDHA11 | c.1660G>A p.V554M | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV56493477; called by muse, mutect2, varscan2
- PCDHA12 | c.1160G>A p.C387Y | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100249631, COSV56502090; called by muse, mutect2, varscan2
- PCDHA13 | c.1333del p.V445Wfs*4 | Frame Shift Del (DEL) | VAF 24/99 reads (24%) | catalogued as rs1562791192; called by mutect2, pindel, varscan2
- PCDHA4 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.85); catalogued as rs782061737, COSV100793314; called by muse, mutect2, varscan2
- PCDHAC1 | c.94C>T p.R32W | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs782199565, COSV99165692; called by muse, mutect2, varscan2
- PCDHGA8 | c.688G>A p.V230M | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as rs754946327, COSV53937501; called by muse, mutect2, varscan2
- PCDHGB7 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as rs577411043, COSV53939319; called by muse, mutect2, varscan2
- PCED1B | c.283A>G p.T95A | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV71395302; called by muse, mutect2, varscan2
- PCID2 | c.322A>G p.M108V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as rs1297308989, COSV99872412; called by muse, mutect2, varscan2
- PCNX2 | c.878del p.G293Afs*3 | Frame Shift Del (DEL) | VAF 14/57 reads (25%) | catalogued as COSV99265987; called by mutect2, pindel, varscan2
- PCYT1A | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.928); catalogued as COSV53056488; called by muse, mutect2
- PDE9A | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs770883595, COSV52325745, COSV52333182; called by muse, mutect2, varscan2
- PDZRN3 | c.2539C>T p.R847W | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as rs773329304, COSV99728870; called by muse, mutect2, varscan2
- PGGHG | c.582G>T p.E194D | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV101164391; called by muse, mutect2, varscan2
- PHF8 | c.1589G>A p.G530D (on ENST00000357988 / NM_001184896.1; = p.G494D on NM_015107.3) | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.149); catalogued as COSV100154052; called by muse, mutect2, varscan2
- PHLPP1 | c.4731G>T p.K1577N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.119); catalogued as COSV99407955; called by muse, mutect2
- PIF1 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV99164857; called by muse, mutect2
- PIGR | c.2177A>G p.K726R | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100732479; called by muse, mutect2, varscan2
- PIM3 | c.670C>A p.R224S | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.182); catalogued as COSV100638406; called by muse, mutect2, varscan2
- PKP4 | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs372850713; called by muse, mutect2, varscan2
- PLD4 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV101190481; called by muse, mutect2, varscan2
- PLEKHG4 | c.2737G>A p.A913T | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1341196819, COSV100430833; called by muse, mutect2, varscan2
- PLEKHG4B | c.2330C>T p.P777L (on ENST00000283426; = p.P1133L on NM_052909.5) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs202113606, COSV52055209, COSV99360115; called by muse, mutect2, varscan2
- PLEKHG7 | c.1126G>A p.V376M | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.358); catalogued as rs370641297, COSV60821279; called by muse, mutect2, varscan2
- PLIN4 | c.3545G>A p.G1182D (on ENST00000301286; = p.G1197D on NM_001367868.2) | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.848); catalogued as COSV100013046; called by muse, mutect2, varscan2
- PLK4 | c.2894C>T p.P965L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.319); catalogued as rs770530003, COSV99584571; called by muse, mutect2, varscan2
- PLXNA1 | c.2641C>T p.R881W | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as rs762983679, COSV99302777; called by muse, mutect2, varscan2
- PLXNA2 | c.4282C>T p.R1428W | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747671301, COSV100885325; called by muse, mutect2, varscan2
- POLM | c.1343G>A p.S448N | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV99641754; called by muse, mutect2, varscan2
- POMC | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV53034379; called by mutect2, varscan2
- POU3F3 | c.1333C>T p.L445F | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100796850; called by muse, mutect2, varscan2
- PPP1R26 | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs149526868; called by muse, mutect2, varscan2
- PRDM16 | c.2617C>T p.R873W | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754375101, COSV99576231; called by muse, mutect2, varscan2
- PRTG | c.1600C>A p.L534I | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.798); catalogued as COSV101221347; called by muse, mutect2
- PTGER3 | c.247A>G p.K83E | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV100138664; called by muse, mutect2, varscan2
- PTGIS | c.1349G>T p.S450I | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV99720839; called by muse, mutect2, varscan2
- PTPRF | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.111); catalogued as COSV100740794; called by muse, mutect2, varscan2
- R3HDM2 | c.2737del p.D913Tfs*41 | Frame Shift Del (DEL) | VAF 9/52 reads (17%) | catalogued as COSV100234622; called by mutect2, pindel, varscan2
- RABL6 | c.139G>A p.V47M | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100273186; called by muse, mutect2, varscan2
- RALGAPA1 | c.448A>C p.M150L | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV99354201; called by muse, mutect2, varscan2
- RALGPS1 | c.1259C>T p.P420L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs768682056, COSV52219554; called by muse, mutect2, varscan2
- RAP2C | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs749217667, COSV100747312; called by muse, mutect2, varscan2
- RARA | c.824C>T p.T275M | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs757750800, COSV54192558; called by muse, mutect2, varscan2
- RASL10A | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99329474; called by muse, mutect2, varscan2
- RBFA | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.863); catalogued as rs765671980, COSV100080164; called by muse, mutect2, varscan2
- RDM1 | c.800A>T p.Y267F | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.069); catalogued as rs138443064; called by muse, mutect2
- RGP1 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs776216680, COSV65239852; called by muse, mutect2, varscan2
- RGPD2 | c.5098G>A p.V1700M | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.593); catalogued as rs1196717117, COSV59531273; called by mutect2, varscan2
- RHEX | c.290G>T p.S97I | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as COSV100520073; called by muse, mutect2, varscan2
- RIC1 | c.1730C>T p.A577V | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.704); catalogued as COSV99317066; called by muse, mutect2, varscan2
- RIC1 | c.2635A>G p.I879V | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs1037091950, COSV99317068; called by muse, mutect2, varscan2
- RIOX2 | c.996G>T p.K332N (on ENST00000333396 / NM_001042533.2; = p.K331N on NM_032778.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as COSV99476869; called by muse, mutect2, varscan2
- RNF213 | c.1271G>A p.R424K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100173350; called by muse, mutect2, varscan2
- RNF213 | c.12991G>A p.G4331S | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs781405923, COSV60396431; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 11/66 reads (17%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNGTT | c.1255T>G p.C419G | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs376912772; called by muse, mutect2, varscan2
- RP1 | c.2674G>A p.A892T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.276); catalogued as COSV99607035; called by muse, mutect2, varscan2
- RPN2 | c.71C>T p.T24M | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs755181709, COSV52904881; called by muse, mutect2, varscan2
- RPS6KA6 | c.327del p.A110Pfs*3 | Frame Shift Del (DEL) | VAF 24/87 reads (28%) | catalogued as rs756096568; called by mutect2, pindel, varscan2
- RSPH3 | c.1207C>T p.R403C (on ENST00000252655; = p.R261C on NM_031924.8) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs755422448, COSV51921221; called by muse, mutect2, varscan2
- RUVBL2 | c.1335G>T p.E445D | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99668943; called by muse, mutect2, varscan2
- RXFP3 | c.1194G>T p.K398N | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100347471; called by muse, mutect2, varscan2
- RYR2 | c.4268C>T p.T1423M | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); catalogued as rs534750117, COSV100769422; called by muse, mutect2, varscan2
- SALL3 | c.1615G>A p.G539S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as rs760958244, COSV101609976; called by muse, mutect2
- SALL4 | c.2983del p.V995Ffs*14 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | catalogued as rs753320334; called by mutect2, pindel, varscan2
- SALL4 | c.496del p.Q166Rfs*3 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | catalogued as CM042108; called by mutect2, pindel, varscan2
- SBNO2 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100684383, COSV62320296; called by muse, mutect2, varscan2
- SEC31B | c.1594C>G p.H532D | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as COSV100947286; called by muse, mutect2, varscan2
- SEPTIN2 | c.223dup p.I75Nfs*2 | Frame Shift Ins (INS) | VAF 8/33 reads (24%) | catalogued as rs758354393; called by mutect2, pindel, varscan2
- SERPINB13 | c.19G>A p.V7I | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs139825462; called by muse, mutect2, varscan2
- SERPINH1 | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1260506914, COSV100825048; called by muse, mutect2, varscan2
- SETDB1 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV54977855; called by muse, mutect2
- SLAIN2 | c.504del p.K168Nfs*27 | Frame Shift Del (DEL) | VAF 12/63 reads (19%) | catalogued as rs769982983; called by mutect2, pindel, varscan2
- SLC12A3 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs545989306, COSV99344054; called by muse, mutect2, varscan2
- SLC12A7 | c.2056del p.H686Tfs*11 | Frame Shift Del (DEL) | VAF 29/116 reads (25%) | catalogued as rs767964038; called by mutect2, pindel, varscan2
- SLC35D3 | c.829G>A p.V277M | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as rs1422645669, COSV100090467; called by muse, mutect2, varscan2
- SLC5A2 | c.1489C>A p.L497M | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as COSV100393130; called by muse, mutect2
- SLC6A17 | c.1812G>T p.E604D | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.029); catalogued as COSV100521209; called by muse, mutect2, varscan2
- SLC7A9 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs768466784, CM023752, COSV50090628; called by muse, mutect2, varscan2
- SLITRK3 | c.983C>A p.S328Y | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV99578957; called by muse, mutect2, varscan2
- SMAP1 | c.607A>T p.K203* (on ENST00000370455 / NM_001044305.3; = p.K176* on NM_021940.5) | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as COSV100391091; called by muse, mutect2, varscan2
- SMARCA2 | c.2132G>T p.R711M | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as COSV100570694; called by muse, mutect2, varscan2
- SORBS2 | c.898_900del p.P300del (on ENST00000284776 / NM_021069.5; = p.P393del on NM_003603.6) | In Frame Del (DEL) | VAF 7/32 reads (22%) | catalogued as rs774575224; called by mutect2, pindel, varscan2
- SPRED1 | c.1207C>T p.R403* | Nonsense Mutation (SNP) | VAF 12/52 reads (23%) | catalogued as rs1201851975, COSV54437723; called by muse, mutect2, varscan2
- SPTA1 | c.5111C>T p.A1704V | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV100934706; called by muse, mutect2, varscan2
- SREBF1 | c.2062G>A p.G688R | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1016697916, COSV55418019; called by muse, mutect2, varscan2
- SREBF1 | c.1957C>T p.Q653* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as COSV99888665; called by muse, mutect2, varscan2
- SRL | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.966); catalogued as rs775040662, COSV68423262; called by muse, mutect2, varscan2
- SSBP2 | c.1084T>C p.*362Rext*52 | Nonstop Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as COSV100283312; called by muse, mutect2, varscan2
- ST7L | c.1340A>C p.Q447P | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as rs895811724, COSV100573727; called by muse, mutect2, varscan2
- STAB1 | c.5834G>A p.G1945D | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100194751; called by muse, mutect2, varscan2
- STAG3 | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs149765159; called by muse, mutect2, varscan2
- STUM | c.391G>T p.G131C | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100828238; called by muse, mutect2, varscan2
- SYCE2 | c.333G>T p.E111D | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as COSV99535840; called by muse, mutect2, varscan2
- SYNJ2 | c.3590C>T p.A1197V | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.164); catalogued as rs1389031130, COSV100840131; called by muse, mutect2
- SYT16 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs200117132; called by muse, mutect2, varscan2
- SYT2 | c.1094T>C p.L365P | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100937126; called by muse, mutect2, varscan2
- TAF6 | c.765G>T p.M255I | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.297); catalogued as COSV100612677; called by muse, mutect2, varscan2
- TALDO1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs773580366, COSV59797423; called by muse, mutect2, varscan2
- TBCD | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100833010; called by muse, mutect2, varscan2
- TBL1X | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV54279803; called by muse, mutect2, varscan2
- TBX6 | c.1201G>A p.A401T | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV99661593; called by muse, mutect2, varscan2
- TCF7 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV100389889; called by muse, mutect2, varscan2
- TENM2 | c.4076G>T p.R1359I (on ENST00000518659 / NM_001122679.2; = p.R1120I on NM_001080428.3) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV101318459; called by muse, mutect2, varscan2
- TENM3 | c.2464A>G p.I822V | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs775005128, COSV101305025; called by muse, mutect2, varscan2
- TET1 | c.279C>G p.N93K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV101017943; called by muse, mutect2, varscan2
- TEX13B | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV100258329; called by muse, mutect2, varscan2
- TFB2M | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200729611, COSV100830439; called by muse, mutect2, varscan2
- TGFB3 | c.272G>A p.C91Y | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1386422914, COSV99472459; called by muse, mutect2, varscan2
- TICRR | c.2177G>A p.R726H | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.095); catalogued as rs750186344, COSV51547579, COSV51549071; called by muse, mutect2, varscan2
- TMEM30A | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 5/42 reads (12%) | catalogued as rs1195661994, COSV57874668; called by muse, mutect2, varscan2
- TMEM94 | c.3712G>A p.A1238T | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.104); catalogued as rs777626356, COSV58594581; called by muse, mutect2, varscan2
- TMPO | c.1715C>T p.A572V | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.035); catalogued as COSV99701962; called by muse, mutect2, varscan2
- TMPRSS15 | c.2384C>T p.A795V | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.715); catalogued as COSV99517573; called by muse, mutect2, varscan2
- TNIK | c.1787T>C p.V596A | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.074); catalogued as COSV52685728; called by muse, mutect2
- TNRC18 | c.2032C>T p.R678* | Nonsense Mutation (SNP) | VAF 13/27 reads (48%) | catalogued as rs1179284195, COSV101259408; called by muse, mutect2, varscan2
- TNS3 | c.3115G>T p.A1039S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs368126646, COSV100235356; called by muse, mutect2, varscan2
- TOX | c.1354C>T p.Q452* | Nonsense Mutation (SNP) | VAF 19/80 reads (24%) | catalogued as COSV100789271; called by muse, mutect2, varscan2
- TPO | c.2119G>A p.D707N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV61095169; called by muse, mutect2, varscan2
- TRANK1 | c.7637G>A p.R2546Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375887057, COSV100083162; called by muse, mutect2, varscan2
- TRAPPC9 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.872); catalogued as COSV101227177; called by muse, mutect2, varscan2
- TREH | c.1474T>G p.F492V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.348); catalogued as COSV99874345; called by muse, mutect2, varscan2
- TRIM37 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs752728939, COSV99232712; called by muse, mutect2, varscan2
- TSR2 | c.41C>A p.A14D | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.014); catalogued as COSV100911007; called by muse, mutect2, varscan2
- TSSK2 | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1473065515, COSV52817201; called by muse, mutect2, varscan2
- TTLL4 | c.361T>C p.S121P | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.353); catalogued as rs1233975474, COSV99293225; called by muse, mutect2, varscan2
- TTN | c.82030G>T p.G27344* (on ENST00000591111; = p.G19920* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as COSV100605094, COSV59901297; called by muse, mutect2, varscan2
- TTN | c.6491C>T p.A2164V (on ENST00000591111; = p.A2118V on NM_003319.4) | Missense Mutation (SNP) | VAF 17/33 reads (52%) | PolyPhen probably damaging (0.96); catalogued as rs1338410239, COSV100605096; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.1364C>A p.T455K | Missense Mutation (SNP) | VAF 30/78 reads (38%) | PolyPhen benign (0.04); catalogued as COSV100605102; called by muse, mutect2, varscan2
- UHRF1BP1L | c.3215dup p.V1073Sfs*2 | Frame Shift Ins (INS) | VAF 7/16 reads (44%) | catalogued as rs750418659; called by mutect2, varscan2
- USP28 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99134973; called by muse, mutect2, varscan2
- UTRN | c.2678T>C p.V893A | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs774195329, COSV100839799; called by muse, mutect2, varscan2
- VN1R1 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.157); catalogued as COSV100320647; called by muse, mutect2, varscan2
- VPS4B | c.341del p.K114Rfs*13 | Frame Shift Del (DEL) | VAF 14/65 reads (22%) | catalogued as rs750318908, COSV99448403; called by mutect2, pindel, varscan2
- VPS53 | c.734C>T p.A245V (on ENST00000571805 / NM_001366253.2; = p.A216V on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as COSV52136069; called by muse, mutect2, varscan2
- WDR1 | c.1762C>T p.H588Y (on ENST00000382452; = p.H448Y on NM_005112.5) | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as COSV101221093; called by muse, mutect2, varscan2
- WDR47 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63058721; called by muse, mutect2, varscan2
- WDR76 | c.691C>A p.P231T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as COSV99776276; called by muse, mutect2, varscan2
- WNT2B | c.887G>A p.R296Q (on ENST00000369684 / NM_024494.3; = p.R277Q on NM_004185.4) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.42); catalogued as rs778364209, COSV99861545; called by muse, mutect2, varscan2
- WNT3 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV56645266; called by muse, mutect2, varscan2
- XPR1 | c.1597G>A p.D533N | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100851447; called by muse, mutect2, varscan2
- XYLT1 | c.2027+1G>A p.X676_splice | Splice Site (SNP) | VAF 12/33 reads (36%) | catalogued as COSV99761233; called by muse, mutect2
- XYLT1 | c.1379G>A p.R460Q | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs987670411, COSV99761236; called by muse, mutect2, varscan2
- YLPM1 | c.5905A>G p.K1969E | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV99459278; called by muse, mutect2, varscan2
- YME1L1 | c.340C>T p.P114S (on ENST00000326799 / NM_139312.3; = p.P57S on NM_014263.4) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as COSV100463517, COSV58760253; called by muse, mutect2, varscan2
- ZBED1 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs766602788, COSV100585429; called by muse, varscan2
- ZBED1 | c.263A>G p.E88G | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as COSV100585431; called by muse, varscan2
- ZBTB25 | c.464G>A p.S155N | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV101170713; called by muse, mutect2, varscan2
- ZC3H6 | c.3229dup p.S1077Kfs*7 | Frame Shift Ins (INS) | VAF 8/32 reads (25%) | catalogued as rs768934713; called by mutect2, varscan2
- ZFYVE16 | c.1465G>A p.V489I | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs764575944, COSV100566317; called by muse, mutect2, varscan2
- ZNF207 | c.320del p.K107Rfs*57 | Frame Shift Del (DEL) | VAF 10/21 reads (48%) | catalogued as rs748924817, COSV58300448, COSV58302045; called by mutect2, varscan2
- ZNF283 | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.36); catalogued as rs1329482809, COSV100190446; called by muse, mutect2, varscan2
- ZNF354A | c.416del p.K139Rfs*6 | Frame Shift Del (DEL) | VAF 17/59 reads (29%) | catalogued as rs1212377728, COSV59982405; called by mutect2, pindel, varscan2
- ZNF354C | c.11A>G p.D4G | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.314); catalogued as COSV100203582; called by muse, mutect2, varscan2
- ZNF404 | c.1324A>T p.K442* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as COSV100182476; called by muse, mutect2, varscan2
- ZNF48 | c.1325C>T p.P442L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.981); catalogued as COSV100198090; called by muse, mutect2, varscan2
- ZNF559 | c.392C>A p.P131H | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.135); catalogued as COSV100416507; called by muse, mutect2
- ZNF57 | c.476T>C p.V159A | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs1215454688, COSV100182861; called by muse, mutect2, varscan2
- ZNF607 | c.1613G>A p.C538Y | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100777864; called by muse, mutect2, varscan2
- ZNF609 | c.2201del p.K734Rfs*12 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs760768847; called by mutect2, varscan2
- ZNF672 | c.1004G>A p.G335D | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV100129127; called by muse, mutect2, varscan2
- ZNF804A | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.037); catalogued as COSV100166392, COSV100167335; called by muse, varscan2
- ZSWIM8 | c.1016T>A p.L339Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101289858; called by muse, mutect2, varscan2
- ZSWIM8 | c.1867C>A p.L623M | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.548); catalogued as COSV101289859; called by muse, mutect2, varscan2
- ABCA12 | c.1964del p.F655Sfs*9 (on ENST00000272895 / NM_173076.3; = p.F337Sfs*9 on NM_015657.3) | Frame Shift Del (DEL) | VAF 5/35 reads (14%) | called by mutect2, pindel, varscan2
- ADAMTS1 | c.2791del p.R931Efs*3 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | called by mutect2, pindel, varscan2
- ADGRB2 | c.1020del p.Y341Mfs*83 | Frame Shift Del (DEL) | VAF 15/31 reads (48%) | called by mutect2, pindel, varscan2
- AKAP11 | c.3140del p.K1047Sfs*4 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- AL592490.1 | c.347del p.P116Lfs*11 | Frame Shift Del (DEL) | VAF 14/59 reads (24%) | called by mutect2, pindel, varscan2
- ALDH9A1 | c.1526_1527dup p.E510Wfs*15 | Frame Shift Ins (INS) | VAF 7/44 reads (16%) | called by mutect2, varscan2
- AMER3 | c.585dup p.R196Afs*11 | Frame Shift Ins (INS) | VAF 9/40 reads (23%) | called by mutect2, pindel, varscan2
- ARAF | c.23del p.P8Lfs*26 | Frame Shift Del (DEL) | VAF 18/57 reads (32%) | called by mutect2, pindel, varscan2
- AREG | c.407del p.N136Ifs*27 | Frame Shift Del (DEL) | VAF 33/122 reads (27%) | called by mutect2, pindel, varscan2
- ARHGEF35 | c.1165del p.A389Qfs*22 | Frame Shift Del (DEL) | VAF 13/30 reads (43%) | called by mutect2, pindel, varscan2
- ARID1A | c.4537_4538del p.S1513Hfs*18 | Frame Shift Del (DEL) | VAF 7/50 reads (14%) | called by pindel, varscan2
- ARTN | c.44C>A p.P15H | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.339); called by muse, mutect2
- ATN1 | c.2622del p.Y875Tfs*78 | Frame Shift Del (DEL) | VAF 10/37 reads (27%) | called by mutect2, pindel, varscan2
- AWAT1 | c.313del p.H105Mfs*4 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | called by mutect2, pindel
- BAP1 | c.362del p.G121Vfs*66 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel, varscan2
- BCLAF1 | c.504del p.A169Lfs*11 | Frame Shift Del (DEL) | VAF 5/37 reads (14%) | called by mutect2, pindel, varscan2
- BRMS1 | c.321del p.L108Cfs*22 | Frame Shift Del (DEL) | VAF 5/15 reads (33%) | called by mutect2, varscan2
- C2orf42 | c.1del p.M1? | Frame Shift Del (DEL) | VAF 8/12 reads (67%) | called by mutect2, varscan2
- CCDC178 | c.873_874del p.K291Nfs*11 | Frame Shift Del (DEL) | VAF 22/80 reads (28%) | called by mutect2, varscan2
- CLPX | c.402del p.F134Lfs*13 | Frame Shift Del (DEL) | VAF 15/56 reads (27%) | called by mutect2, pindel, varscan2
- COG1 | c.2798_2799del p.K933Sfs*13 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | called by mutect2, pindel, varscan2
- COL9A2 | c.908del p.P303Qfs*15 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- CTR9 | c.2320del p.S774Vfs*3 | Frame Shift Del (DEL) | VAF 15/66 reads (23%) | called by mutect2, pindel, varscan2
- CTSC | c.315del p.F105Lfs*10 | Frame Shift Del (DEL) | VAF 5/21 reads (24%) | called by mutect2, pindel, varscan2
- CXCL16 | c.584del p.N195Mfs*82 | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | called by mutect2, pindel, varscan2
- CYP4Z1 | c.1509del p.V504Ffs*36 | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | called by mutect2, pindel
- DAGLA | c.2749_2751del p.I917del | In Frame Del (DEL) | VAF 9/38 reads (24%) | called by mutect2, pindel, varscan2
- DHX9 | c.220_224del p.E74Kfs*3 | Frame Shift Del (DEL) | VAF 14/30 reads (47%) | called by mutect2, varscan2
- DMRTB1 | c.890del p.P297Rfs*13 | Frame Shift Del (DEL) | VAF 31/115 reads (27%) | called by mutect2, pindel, varscan2
- DRD2 | c.924del p.D309Tfs*50 | Frame Shift Del (DEL) | VAF 39/159 reads (25%) | called by mutect2, pindel, varscan2
- ENTPD1 | c.900del p.C301Afs*7 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | called by mutect2, pindel, varscan2
- EOMES | c.995del p.G332Afs*4 | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | called by mutect2, pindel, varscan2
- FAM133A | c.157del p.T53Qfs*6 | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | called by mutect2, pindel, varscan2
- FOXN2 | c.502_505del p.K168Vfs*33 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel, varscan2
- GALC | c.1884del p.K628Nfs*7 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- GALNT5 | c.202del p.Y68Tfs*4 | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | called by mutect2, pindel
- GAP43 | c.41dup p.N14Kfs*2 | Frame Shift Ins (INS) | VAF 8/46 reads (17%) | called by mutect2, varscan2
- GBP2 | c.1589C>A p.T530N | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.851); called by muse, mutect2
- GPR160 | c.715del p.I239Yfs*22 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | called by mutect2, pindel, varscan2
- GRM3 | c.579dup p.D194Rfs*10 | Frame Shift Ins (INS) | VAF 24/62 reads (39%) | called by mutect2, pindel, varscan2
- HNRNPM | c.158del p.N53Tfs*2 | Frame Shift Del (DEL) | VAF 20/53 reads (38%) | called by mutect2, pindel, varscan2
- IQGAP1 | c.2808dup p.L937Tfs*6 | Frame Shift Ins (INS) | VAF 11/41 reads (27%) | called by mutect2, pindel, varscan2
- KIF3C | c.1924_1926del p.E642del | In Frame Del (DEL) | VAF 17/71 reads (24%) | called by pindel, varscan2
- KIF5B | c.1864del p.M622Wfs*8 | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | called by mutect2, pindel, varscan2
- KMO | c.1259del p.K420Rfs*2 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | called by mutect2, varscan2
- LCORL | c.715del p.T239Pfs*3 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- LCT | c.2560del p.R854Dfs*8 | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | called by mutect2, pindel, varscan2
- MACROH2A2 | c.438del p.K147Rfs*53 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | called by mutect2, pindel, varscan2
- MAST3 | c.953T>A p.I318N | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MCAM | c.1375del p.R459Gfs*23 | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | called by mutect2, pindel, varscan2
- MICB | c.763del p.D255Mfs*90 | Frame Shift Del (DEL) | VAF 11/62 reads (18%) | called by mutect2, pindel, varscan2
- MIDN | c.781del p.R261Afs*13 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel, varscan2
- MTSS2 | c.94_96del p.F32del | In Frame Del (DEL) | VAF 9/43 reads (21%) | called by mutect2, pindel, varscan2
- MUC21 | c.1612del p.H538Tfs*18 | Frame Shift Del (DEL) | VAF 5/19 reads (26%) | called by mutect2, pindel, varscan2
- MYSM1 | c.1701del p.F567Lfs*11 | Frame Shift Del (DEL) | VAF 27/133 reads (20%) | called by mutect2, pindel, varscan2
- NBR1 | c.1620del p.N540Kfs*16 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- NEFM | c.1683del p.E562Rfs*157 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | called by mutect2, varscan2
- NINL | c.3136del p.E1046Rfs*4 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel, varscan2
- NSMCE2 | c.289del p.I97Yfs*4 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | called by mutect2, pindel, varscan2
- OR5F1 | c.679dup p.S227Ffs*37 | Frame Shift Ins (INS) | VAF 7/28 reads (25%) | called by mutect2, varscan2
- PHACTR2 | c.587del p.N196Ifs*80 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, varscan2
- PHF3 | c.4519dup p.I1507Nfs*6 | Frame Shift Ins (INS) | VAF 5/19 reads (26%) | called by mutect2, pindel, varscan2
- PLA2G4D | c.2229dup p.G744Rfs*43 | Frame Shift Ins (INS) | VAF 11/57 reads (19%) | called by mutect2, pindel
- PRAMEF6 | c.1249del p.R417Gfs*22 | Frame Shift Del (DEL) | VAF 61/375 reads (16%) | called by mutect2, pindel, varscan2
- PSMF1 | c.479del p.P160Lfs*39 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | called by mutect2, pindel, varscan2
- PTK2B | c.985del p.Q329Rfs*10 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- RAB31 | c.455del p.N152Mfs*54 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, pindel, varscan2
- SCEL | c.968del p.N323Mfs*14 (on ENST00000349847 / NM_144777.3; = p.N303Mfs*14 on NM_003843.4) | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | called by mutect2, pindel, varscan2
- SEC14L1 | c.474del p.G159Efs*12 | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | called by mutect2, pindel, varscan2
- SEL1L3 | c.2823del p.Q942Kfs*10 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- SH2B1 | c.1423del p.R475Afs*68 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | called by mutect2, varscan2
- SLC27A4 | c.862del p.L288Sfs*19 | Frame Shift Del (DEL) | VAF 11/46 reads (24%) | called by mutect2, pindel, varscan2
- SLC28A1 | c.1763-23_1780delinsACCCACCACTTTCCCTCTACAGGGATCCTCTACATGCCCAG p.X588_splice | Splice Site (ONP) | VAF 17/85 reads (20%) | called by mutect2*, pindel, varscan2*
- SLFN12 | c.91del p.M31* | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, varscan2
- SMC4 | c.1239dup p.L414Tfs*9 | Frame Shift Ins (INS) | VAF 4/16 reads (25%) | called by mutect2, pindel, varscan2
- SP4 | c.1435_1436del p.L480Ffs*52 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | called by pindel, varscan2
- SPATA1 | c.658del p.S220Vfs*45 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | called by mutect2, pindel, varscan2
- SPDL1 | c.1509del p.K503Nfs*9 | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | called by mutect2, pindel, varscan2
- SRCIN1 | c.248T>C p.F83S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SRPX | c.677del p.P226Qfs*32 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | called by mutect2, pindel, varscan2
- SUPT20HL2 | c.1123C>A p.Q375K | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SYNE1 | c.1599_1602del p.R533Sfs*14 (on ENST00000367255 / NM_182961.4; = p.R540Sfs*14 on NM_033071.3) | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | called by mutect2, pindel
- TARS3 | c.464dup p.D157Gfs*12 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by pindel, varscan2
- TCF7 | c.463del p.H155Tfs*44 | Frame Shift Del (DEL) | VAF 20/52 reads (38%) | called by mutect2, pindel, varscan2
- TTBK2 | c.2699del p.L900Cfs*40 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | called by mutect2, pindel, varscan2
- VIRMA | c.3331del p.S1111Lfs*51 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | called by mutect2, pindel, varscan2
- ZFYVE9 | c.963dup p.E322Rfs*9 | Frame Shift Ins (INS) | VAF 5/10 reads (50%) | called by mutect2, varscan2
- ZSCAN26 | c.1309C>A p.L437I (on ENST00000623276 / NM_001111039.2; = p.L303I on NM_152736.5) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ABL2 | c.2622G>A p.K874= (on ENST00000502732 / NM_007314.4; = p.K859= on NM_005158.5) | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as rs898141087, COSV100772630; called by muse, mutect2, varscan2
- ACBD3 | c.1195C>A p.R399= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV100830973; called by muse, mutect2, varscan2
- ACSM3 | c.699C>T p.F233= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV99184291; called by muse, mutect2, varscan2
- AFAP1L1 | c.1170G>T p.A390= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99695806; called by mutect2, varscan2
- AFF4 | c.723A>G p.S241= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as rs1213823394, COSV99534810; called by muse, mutect2, varscan2
- AGRN | c.6132C>T p.T2044= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs752905025, COSV101038735; called by muse, mutect2, varscan2
- AGXT2 | c.987G>A p.L329= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV99183733; called by muse, mutect2, varscan2
- ANAPC4 | c.922C>T p.L308= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV100193950; called by muse, mutect2, varscan2
- ARHGAP32 | c.3897G>A p.T1299= (on ENST00000310343 / NM_001378025.1; = p.T950= on NM_014715.4) | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs754710272, COSV59854209; called by muse, mutect2, varscan2
- ARHGAP39 | c.1290G>A p.Q430= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs1164131732, COSV99430826; called by muse, mutect2, varscan2
- ARHGAP45 | c.1959G>A p.S653= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV57430595; called by muse, mutect2, varscan2
- ARIH2 | c.75A>G p.E25= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs1374067563, COSV62706294; called by muse, mutect2, varscan2
- ATP9B | c.2988G>A p.P996= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs749884882, COSV100303321; called by muse, mutect2, varscan2
- BAZ2B | c.582A>G p.S194= | Silent (SNP) | VAF 35/111 reads (32%) | catalogued as COSV100600539; called by muse, mutect2, varscan2
- BCL11A | c.1887C>T p.Y629= (on ENST00000335712 / NM_001365609.1; = p.Y663= on NM_018014.4) | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs1196538777, COSV59623973; called by muse, mutect2, varscan2
- BCL9 | c.2301G>A p.L767= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV99324874; called by mutect2, varscan2
- BNC1 | c.1134C>T p.A378= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs764706422, COSV100597091; called by muse, mutect2, varscan2
- C1GALT1C1 | c.384C>T p.Y128= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs1004336111, COSV58973899; called by muse, mutect2, varscan2
- CADPS | c.1800C>T p.D600= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV99337311; called by muse, mutect2, varscan2
- CALML3 | c.294C>T p.N98= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs1380059416, COSV59449530; called by muse, mutect2
- CASZ1 | c.3876G>A p.K1292= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100681144; called by muse, mutect2, varscan2
- CDC20B | c.1305T>C p.A435= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV99696764; called by muse, mutect2, varscan2
- CDH20 | c.2304G>A p.S768= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs756107421, COSV99405004; called by muse, mutect2
- CDK4 | c.42C>T p.V14= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs786203182, COSV99225950; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CHRNA3 | c.1110G>A p.R370= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV58775424; called by muse, mutect2, varscan2
- CHRNB1 | c.261G>A p.R87= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV99548220; called by muse, mutect2, varscan2
- CLCN6 | c.768G>A p.A256= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as rs372922502; called by muse, mutect2, varscan2
- CMTM3 | c.324C>T p.T108= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs557142222, COSV100726187; called by muse, mutect2, varscan2
- CNTN4 | c.1413C>T p.D471= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as rs1037405854, COSV61867980; called by muse, mutect2, varscan2
- CNTNAP4 | c.756G>A p.L252= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs781322119, COSV100270621; called by muse, mutect2, varscan2
- COL10A1 | c.687A>G p.G229= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV99684177; called by muse, mutect2, varscan2
- COL4A3 | c.402T>C p.F134= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as CD1511093, COSV101170215; called by muse, mutect2, varscan2
- COL5A1 | c.3450T>C p.G1150= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV100879762; called by muse, mutect2, varscan2
- CSTF1 | c.93C>T p.A31= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV99410145; called by muse, mutect2, varscan2
- CXXC5 | c.966G>A p.Q322= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV100210666; called by muse, mutect2, varscan2
- DHRS4 | c.825G>A p.P275= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV100365779; called by muse, mutect2, varscan2
- DIO3 | c.246C>T p.P82= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs767489524, COSV100832090; called by muse, mutect2, varscan2
- DNAH10 | c.10228C>T p.L3410= (on ENST00000409039; = p.L3349= on NM_207437.3) | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV101292163; called by muse, mutect2, varscan2
- DOCK10 | c.4875C>T p.G1625= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV99288839; called by muse, mutect2, varscan2
- DOCK3 | c.2766G>A p.S922= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as rs761737213, COSV56540309; called by muse, mutect2, varscan2
- DOK2 | c.213C>T p.A71= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs749348418, COSV99374664; called by muse, varscan2
- DPP6 | c.870C>T p.D290= (on ENST00000377770 / NM_001364500.2; = p.D228= on NM_001936.5) | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV100124540; called by muse, mutect2, varscan2
- DPYSL5 | c.1533C>T p.L511= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs1196115487, COSV56515187; called by muse, mutect2, varscan2
- DRD5 | c.951C>T p.C317= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as COSV100431694; called by muse, mutect2, varscan2
- DSP | c.3807A>G p.R1269= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV101131230; called by muse, mutect2, varscan2
- DYNC1H1 | c.10851C>T p.D3617= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs939486667, COSV100794737; called by muse, mutect2, varscan2
- EGF | c.3243C>T p.R1081= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as rs1488123532, COSV99490739; called by muse, mutect2, varscan2
- ENTPD6 | c.1164T>C p.L388= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV100737052; called by muse, mutect2, varscan2
- EPPK1 | c.276G>A p.L92= | Silent (SNP) | VAF 9/96 reads (9%) | catalogued as COSV101599799; called by muse, mutect2
- ERGIC2 | c.222A>G p.L74= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs373979333; called by muse, mutect2
- EXD3 | c.708G>A p.A236= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs369860371; called by muse, mutect2, varscan2
- FANCM | c.3669C>T p.C1223= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as rs765751064, COSV99950884; called by muse, mutect2, varscan2
- FAT1 | c.7380T>C p.F2460= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV101499270; called by muse, mutect2, varscan2
- FBXW5 | c.891C>T p.H297= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs779633041, COSV99812331; called by muse, mutect2, varscan2
- FCGBP | c.5865C>T p.H1955= | Silent (SNP) | VAF 38/532 reads (7%) | catalogued as rs146703868; called by muse, mutect2
- FERD3L | c.399C>T p.Y133= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs1309907693, COSV51762499, COSV51764707; called by muse, mutect2, varscan2
- FFAR1 | c.105G>A p.R35= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs1040577492, COSV99323072; called by muse, mutect2, varscan2
- FFAR3 | c.549C>T p.P183= | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as rs770809369, COSV59909031; called by muse, mutect2, varscan2
- FNDC1 | c.1983C>T p.G661= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV51948166; called by muse, mutect2
- FOXA1 | c.664C>T p.L222= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as COSV99163322; called by muse, mutect2, varscan2
- FOXN1 | c.1815C>T p.S605= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs369425799; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FYCO1 | c.1017G>A p.R339= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV99945490; called by muse, mutect2, varscan2
- GALNTL6 | c.867C>T p.Y289= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV101560214; called by muse, mutect2, varscan2
- GJA10 | c.1105C>T p.L369= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV101005327; called by muse, mutect2, varscan2
- GLS2 | c.1365G>A p.V455= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV100358308; called by muse, mutect2, varscan2
- GRIP2 | c.466C>T p.L156= (on ENST00000619221; = p.L59= on NM_001080423.4) | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV99817172; called by muse, mutect2, varscan2
- GTF2IRD2B | c.1707T>C p.G569= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs370511324; called by muse, mutect2, varscan2
- H4C13 | c.30T>A p.G10= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV100137826; called by muse, mutect2, varscan2
- HCAR2 | c.168C>T p.L56= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV100186468; called by muse, mutect2, varscan2
- HECW1 | c.2103G>A p.S701= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs747334643, COSV67828522; called by muse, mutect2, varscan2
- HEG1 | c.1143G>A p.S381= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as rs774359727, COSV100230362; called by muse, mutect2, varscan2
- HELZ2 | c.4950C>T p.C1650= (on ENST00000467148 / NM_001037335.2; = p.C1081= on NM_033405.3) | Silent (SNP) | VAF 13/21 reads (62%) | catalogued as COSV101427546; called by muse, mutect2, varscan2
- HK3 | c.234C>T p.Y78= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as rs769304037, COSV99457707; called by muse, mutect2, varscan2
- HLX | c.750T>C p.H250= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV100854513; called by muse, mutect2, varscan2
- HMCN1 | c.6429C>A p.P2143= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV99627470; called by muse, mutect2, varscan2
- HMGCS2 | c.1521C>A p.P507= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV101024760, COSV65569638; called by muse, mutect2, varscan2
- IGF2R | c.1761G>A p.K587= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV100807199; called by muse, mutect2, varscan2
- IGF2R | c.5487C>T p.R1829= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as rs144649257; called by muse, mutect2, varscan2
- IMPDH1 | c.903G>A p.G301= (on ENST00000470772 / NM_001142573.2; = p.G387= on NM_000883.4) | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV58317331; called by muse, mutect2, varscan2
- INHBB | c.888C>T p.C296= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as rs140523491; called by muse, mutect2, varscan2
- IPO8 | c.1845T>C p.I615= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV99805097; called by muse, mutect2, varscan2
- KAT2B | c.1002G>A p.L334= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV99769135; called by mutect2, varscan2
- KCNJ13 | c.864C>T p.Y288= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs1231316689, COSV99289286; called by muse, mutect2, varscan2
- KDM5A | c.2469G>T p.V823= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV101238737; called by muse, mutect2, varscan2
- KIAA1109 | c.7410A>T p.S2470= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV99151538; called by muse, mutect2, varscan2
- KIF13A | c.1803G>A p.V601= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV99435260; called by muse, mutect2, varscan2
- LAMC1 | c.4296C>T p.I1432= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as rs1358421918, COSV51132330; called by muse, mutect2, varscan2
- LPIN3 | c.2289C>A p.A763= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV100182495; called by muse, mutect2, varscan2
- LVRN | c.951C>T p.H317= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs760170484, COSV100773400; called by muse, mutect2, varscan2
- MAML2 | c.2196C>T p.C732= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV73264446; called by muse, mutect2, varscan2
- MAMSTR | c.969C>A p.P323= (on ENST00000318083 / NM_001130915.2; = p.P220= on NM_182574.2) | Silent (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- MAP7D2 | c.303G>A p.Q101= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV101107295; called by muse, mutect2, varscan2
- MED12 | c.1659C>T p.I553= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs763388314, COSV100377282; ClinVar: likely benign; called by muse, mutect2, varscan2
- MINK1 | c.3198G>A p.L1066= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV99544784; called by mutect2, varscan2
- MLH3 | c.3402T>C p.S1134= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV99470066; called by muse, mutect2, varscan2
- MLPH | c.1299G>A p.T433= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs140569108; called by muse, mutect2
- MPDZ | c.5664G>A p.V1888= (on ENST00000319217 / NM_001330637.2; = p.V1859= on NM_003829.5) | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV100056535; called by muse, mutect2, varscan2
- MPZ | c.363C>T p.D121= | Silent (SNP) | VAF 25/110 reads (23%) | catalogued as COSV100337847; called by muse, mutect2, varscan2
- MRPS7 | c.54C>T p.G18= | Silent (SNP) | VAF 45/190 reads (24%) | catalogued as rs766690562, COSV99821545; called by muse, mutect2, varscan2
- MTHFR | c.1950G>A p.A650= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs1300052327, COSV100453543; called by muse, mutect2, varscan2
- MYD88 | c.585C>T p.D195= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as COSV57174007; called by muse, mutect2, varscan2
- NAXE | c.861G>A p.L287= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV100576910; called by muse, mutect2
- NHS | c.2628G>A p.T876= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs773431509, COSV101196444; called by muse, mutect2, varscan2
- NLRP9 | c.2730C>A p.I910= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100242901; called by muse, mutect2, varscan2
- NTM | c.864T>C p.H288= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs750209765, COSV100868201; called by muse, mutect2, varscan2
- OR2B11 | c.705C>T p.S235= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV59511222; called by muse, mutect2, varscan2
- PACSIN1 | c.426C>T p.A142= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs1266456695, COSV99762997; called by muse, mutect2, varscan2
- PCDH11X | c.294T>G p.A98= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV100010832; called by muse, mutect2
- PCDHB12 | c.1797C>T p.N599= | Silent (SNP) | VAF 36/119 reads (30%) | catalogued as rs543256787, COSV53394933; called by muse, mutect2, varscan2
- PDXK | c.309G>A p.Q103= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV99376311; called by muse, mutect2, varscan2
- PHF3 | c.744G>A p.V248= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV100013162, COSV50339362; called by muse, mutect2, varscan2
- PITPNM1 | c.498G>A p.K166= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100039372; called by muse, mutect2, varscan2
- PLA2G3 | c.1294C>T p.L432= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV99311516; called by muse, mutect2, varscan2
- PLEKHA6 | c.507C>A p.P169= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV99691838; called by muse, mutect2, varscan2
- PLXNA3 | c.3694C>T p.L1232= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV100859905; called by muse, mutect2, varscan2
- PNPLA5 | c.600C>T p.T200= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV99336583; called by muse, mutect2, varscan2
- PNPLA8 | c.1602T>C p.S534= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV99993504; called by muse, mutect2, varscan2
- POF1B | c.120G>A p.Q40= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV99426464; called by muse, mutect2, varscan2
- PRELID1 | c.645G>A p.Q215= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs963873066, COSV100293539; called by muse, mutect2, varscan2
- PRICKLE1 | c.1248G>A p.T416= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs142502371; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRRC2C | c.3573C>T p.G1191= (on ENST00000367742; = p.G1189= on NM_015172.4) | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100145065; called by muse, mutect2, varscan2
- PTCH1 | c.4164G>C p.G1388= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV100108134; called by muse, mutect2, varscan2
- PTK6 | c.510C>T p.C170= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs1365743533, COSV99420448; called by muse, mutect2, varscan2
- PWWP3B | c.951C>T p.C317= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs776503123, COSV61799461; called by muse, mutect2, varscan2
- RASGRF2 | c.1746C>T p.D582= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs575059799, COSV99428945; called by muse, mutect2, varscan2
- RER1 | c.432G>A p.P144= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as rs550708145, COSV56579425; called by muse, mutect2, varscan2
- RNF157 | c.1470T>C p.I490= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV99486876; called by mutect2, varscan2
- SEC14L2 | c.93G>A p.P31= | Silent (SNP) | VAF 33/96 reads (34%) | catalogued as rs34330978, COSV100464245; called by muse, mutect2, varscan2
- SERPIND1 | c.201C>T p.N67= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs772705090, COSV99300145; called by muse, mutect2, varscan2
- SH3PXD2B | c.2310G>A p.S770= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs151103801; called by muse, mutect2, varscan2
- SIDT2 | c.1950G>A p.T650= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs779893045, COSV99637516; called by muse, mutect2, varscan2
- SLC19A1 | c.1392G>A p.P464= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs60669093; called by muse, mutect2, varscan2
- SLC1A5 | c.1146C>T p.G382= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs11541232, COSV69467860; called by muse, mutect2, varscan2
- SLC35A2 | c.1110A>G p.P370= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as rs782273947, COSV99504181; called by muse, mutect2, varscan2
- SPINK5 | c.510T>C p.D170= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV99806507; called by muse, mutect2, varscan2
- SRRM1 | c.1122T>G p.P374= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV100104408; called by muse, mutect2, varscan2
- STAB1 | c.1887C>T p.A629= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs745981144, COSV100401529; called by muse, mutect2, varscan2
- TANC1 | c.535C>T p.L179= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV99713583; called by muse, mutect2, varscan2
- TBC1D24 | c.1032C>T p.I344= (on ENST00000646147 / NM_001199107.2; = p.I338= on NM_020705.3) | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV53548083; called by muse, mutect2, varscan2
- TCAF1 | c.2649G>A p.P883= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs1317488568, COSV100584602; called by mutect2, varscan2
- TECTA | c.1854G>A p.T618= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs746142039, COSV99879463; called by muse, mutect2, varscan2
- TMEM131 | c.4800G>A p.P1600= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs200815269, COSV51786303; called by muse, mutect2, varscan2
- TMEM86A | c.378G>A p.A126= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as rs146633157, COSV55012006; called by muse, mutect2, varscan2
- TMPRSS2 | c.783C>T p.S261= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs145355824; called by muse, mutect2, varscan2
- TRAF3IP1 | c.645G>A p.G215= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs1252333845, COSV100966826; called by mutect2, varscan2
- TRDN | c.2136T>C p.P712= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV100521560; called by muse, mutect2, varscan2
- TRIM46 | c.963G>A p.G321= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV99825912; called by muse, mutect2, varscan2
- TRPC7 | c.828C>T p.G276= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs190572796; called by muse, mutect2, varscan2
- TUFM | c.987C>T p.V329= | Silent (SNP) | VAF 33/98 reads (34%) | catalogued as COSV100492493; called by muse, mutect2, varscan2
- TULP2 | c.885C>T p.H295= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs144003818; called by muse, mutect2, varscan2
- VHLL | c.156G>A p.E52= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV100372614; called by muse, mutect2, varscan2
- VPS13A | c.978T>C p.H326= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV100652506; called by muse, mutect2, varscan2
- ZC3H13 | c.4224C>T p.D1408= | Silent (SNP) | VAF 4/67 reads (6%) | catalogued as COSV99667910; called by muse, mutect2
- ZC3H18 | c.291C>T p.C97= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs370000282; called by muse, varscan2
- ZDBF2 | c.441G>A p.Q147= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV65621723; called by muse, mutect2, varscan2
- ZNF750 | c.1593G>A p.T531= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs928667145, COSV99489710; called by muse, mutect2, varscan2
- ZNF83 | c.288T>C p.S96= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV99991306; called by muse, mutect2, varscan2
- AL109984.1 | n.186+1178G>A | Intron (SNP) | VAF 9/31 reads (29%) | catalogued as rs765657938, COSV63751816; called by muse, mutect2, varscan2
- BCL7A | c.561+60G>A | Intron (SNP) | VAF 14/60 reads (23%) | catalogued as rs911951329, COSV99946917; called by muse, mutect2, varscan2
- CAMKK1 | c.-44+2244A>G | Intron (SNP) | VAF 36/115 reads (31%) | catalogued as COSV99340191; called by muse, mutect2, varscan2
- ERCC6 | c.1397+7707T>C | Intron (SNP) | VAF 7/17 reads (41%) | catalogued as COSV100875853; called by muse, mutect2, varscan2
- FAM86C1P | n.183-1570C>T | Intron (SNP) | VAF 39/152 reads (26%) | catalogued as COSV100660650; called by muse, mutect2, varscan2
- FBXL21P | n.975-452C>T | Intron (SNP) | VAF 14/60 reads (23%) | catalogued as COSV99778263; called by muse, mutect2, varscan2
- GABBR1 | c.497-15del | Intron (DEL) | VAF 4/11 reads (36%) | catalogued as rs1274768535; called by mutect2, varscan2
- KAT2B | c.*8del | 3'UTR (DEL) | VAF 8/34 reads (24%) | catalogued as rs750062124; called by mutect2, varscan2
- MPIG6B | c.542-7del | Intron (DEL) | VAF 7/22 reads (32%) | catalogued as rs770605562; called by mutect2, pindel, varscan2
- NVL | c.2183-6718del | Intron (DEL) | VAF 8/22 reads (36%) | catalogued as rs573934358; called by mutect2, varscan2
- RIMS2 | c.177-44402dup | Intron (INS) | VAF 5/20 reads (25%) | called by mutect2, pindel, varscan2
- SEBOX | c.-60G>A | 5'UTR (SNP) | VAF 31/94 reads (33%) | catalogued as COSV99412067; called by muse, mutect2, varscan2
- SLC45A4 | c.242-6467G>A | Intron (SNP) | VAF 14/46 reads (30%) | catalogued as rs142818740; called by muse, mutect2, varscan2
- SNORD114-21 | n.52G>A | RNA (SNP) | VAF 20/53 reads (38%) | catalogued as rs552344318; called by muse, mutect2, varscan2
- SNORD116-1 | n.19del | RNA (DEL) | VAF 15/67 reads (22%) | called by mutect2, pindel, varscan2
- TPM4 | c.*135G>T | 3'UTR (SNP) | VAF 20/84 reads (24%) | catalogued as COSV99959354; called by muse, mutect2, varscan2
